Somatic mutation profile of tumor specimen C3N-03009-01 (aliquot CPT0245060010) from CPTAC case C3N-03009, project CPTAC-3 (Floor of mouth — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Floor of mouth, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 58.9 years (21,529 days).
Specimen C3N-03009-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Floor Of Mouth; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a408326e-5193-483b-b472-4918b3e0dd6b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03009-31 (Blood Derived Normal), aliquot CPT0245120002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/93c49314-ba78-4a85-8808-f3b654a9de6d

The open-access MAF lists 157 somatic variants for this specimen: 116 protein-altering or splice-affecting, 24 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 99, Silent 24, Intron 7, Nonsense Mutation 5, RNA 4, Splice Region 4, Splice Site 3, 5'UTR 3, Frame Shift Del 3, 3'UTR 2, Frame Shift Ins 2, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.3131A>G p.N1044S | Missense Mutation (SNP) | VAF 41/104 reads (39%) | SIFT tolerated (0.19); PolyPhen benign (0.297); catalogued as rs1064793838, COSV55874598, COSV99835810, COSV99841106; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.452C>A p.P151H | Missense Mutation (SNP) | VAF 192/295 reads (65%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.803); catalogued as rs1057520000, COSV52677206, COSV52707835, COSV52811105; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- TP63 | c.580-2A>C p.X194_splice | Splice Site (SNP) | VAF 225/471 reads (48%) | hotspot (GDC flag); catalogued as CS013119, CS135734; called by muse, mutect2, varscan2
- ACAN | c.4325C>T p.A1442V | Missense Mutation (SNP) | VAF 192/736 reads (26%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.792); catalogued as rs1387358007; called by muse, varscan2
- ACTRT2 | c.62G>A p.C21Y | Missense Mutation (SNP) | VAF 59/206 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); catalogued as rs1243794202, COSV101007505; called by muse, mutect2, varscan2
- ACVR1C | c.1082C>T p.P361L | Missense Mutation (SNP) | VAF 64/148 reads (43%) | SIFT tolerated (0.17); PolyPhen benign (0.348); catalogued as COSV54644203; called by muse, mutect2, varscan2
- ADAP2 | c.765C>A p.N255K | Missense Mutation (SNP) | VAF 41/222 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as COSV58296531; called by muse, mutect2, varscan2
- ADGRL2 | c.4249C>T p.H1417Y (on ENST00000370717 / NM_001366005.1; = p.H1361Y on NM_012302.4) | Missense Mutation (SNP) | VAF 29/144 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.217); catalogued as rs1454103691; called by muse, mutect2, varscan2
- AKAP8L | c.1378A>G p.I460V | Missense Mutation (SNP) | VAF 52/433 reads (12%) | SIFT tolerated (0.2); PolyPhen benign (0.105); catalogued as rs781614073; called by muse, mutect2, varscan2
- AKAP9 | c.4912G>T p.A1638S | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT tolerated (0.12); PolyPhen benign (0.426); catalogued as rs749031818, COSV62355378; called by muse, mutect2, varscan2
- ASB12 | c.854G>T p.R285L | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.722); catalogued as COSV100744798; called by muse, mutect2, varscan2
- C19orf71 | c.320C>T p.S107L | Missense Mutation (SNP) | VAF 28/117 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.199); catalogued as rs758594874; called by muse, mutect2, varscan2
- C1orf94 | c.127G>A p.A43T | Missense Mutation (SNP) | VAF 39/207 reads (19%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.811); catalogued as rs755130288, COSV64916127; called by muse, mutect2, varscan2
- CA5A | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 39/202 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); catalogued as rs770132207, COSV59240266; called by muse, mutect2, varscan2
- CELSR1 | c.5159G>A p.R1720Q | Missense Mutation (SNP) | VAF 27/157 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs889046307; called by muse, mutect2, varscan2
- CFAP47 | c.1634A>T p.K545M | Missense Mutation (SNP) | VAF 51/106 reads (48%) | SIFT tolerated (0.31); PolyPhen benign (0.21); catalogued as COSV52884712; called by muse, mutect2, varscan2
- CHAT | c.1351G>C p.V451L | Missense Mutation (SNP) | VAF 55/474 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.822); catalogued as rs779466347; called by muse, mutect2, varscan2
- CSMD3 | c.5666G>A p.R1889K (on ENST00000297405 / NM_001363185.1; = p.R1785K on NM_052900.3) | Missense Mutation (SNP) | VAF 20/250 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.269); catalogued as rs1353279018; called by muse, mutect2
- DNAAF1 | c.460C>T p.R154C | Missense Mutation (SNP) | VAF 212/605 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574238677, COSV57577092; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DPEP3 | c.104G>A p.R35H | Missense Mutation (SNP) | VAF 63/427 reads (15%) | SIFT tolerated, low confidence (0.54); PolyPhen benign (0); catalogued as rs772952483, COSV99262541; called by muse, mutect2, varscan2
- DSC2 | c.818C>T p.P273L | Missense Mutation (SNP) | VAF 50/212 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs864622708; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FAM89A | c.186C>A p.D62E | Missense Mutation (SNP) | VAF 165/404 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.034); catalogued as rs1057463869; called by muse, mutect2, varscan2
- GALNT2 | c.1369C>T p.L457F | Missense Mutation (SNP) | VAF 142/389 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.233); catalogued as COSV100795883; called by muse, mutect2, varscan2
- GFAP | c.127C>T p.P43S | Missense Mutation (SNP) | VAF 30/186 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as rs368169263; called by muse, mutect2, varscan2
- HDAC9 | c.739G>A p.D247N | Missense Mutation (SNP) | VAF 41/241 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.747); catalogued as COSV67766493; called by muse, mutect2, varscan2
- HIP1R | c.2119G>A p.G707S | Missense Mutation (SNP) | VAF 51/390 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1434346109; called by muse, mutect2, varscan2
- MUC6 | c.184G>A p.D62N | Missense Mutation (SNP) | VAF 77/376 reads (20%) | SIFT tolerated (0.19); PolyPhen benign (0.047); catalogued as rs868720704, COSV70147794; called by muse, mutect2, varscan2
- NMD3 | c.-20-7T>A | Splice Region (SNP) | VAF 10/92 reads (11%) | catalogued as rs542572679; called by muse, varscan2
- PCDHB11 | c.124G>T p.G42W | Missense Mutation (SNP) | VAF 182/342 reads (53%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV53384643; called by muse, mutect2, varscan2
- PCDHGC5 | c.902C>A p.A301E | Missense Mutation (SNP) | VAF 65/429 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV99341191; called by muse, mutect2, varscan2
- PCNX3 | c.3971G>T p.R1324L | Missense Mutation (SNP) | VAF 56/376 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.68); catalogued as rs1167960566; called by muse, mutect2, varscan2
- PHACTR4 | c.1027C>T p.P343S (on ENST00000373839 / NM_001350159.2; = p.P353S on NM_023923.4) | Missense Mutation (SNP) | VAF 52/111 reads (47%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.709); catalogued as rs768730507; called by muse, mutect2, varscan2
- PLCG1 | c.2983G>T p.A995S | Missense Mutation (SNP) | VAF 34/253 reads (13%) | SIFT tolerated (0.8); PolyPhen benign (0.001); catalogued as COSV54814941; called by muse, mutect2, varscan2
- POTEJ | c.2953C>T p.P985S | Missense Mutation (SNP) | VAF 102/935 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as rs745738669; called by muse, mutect2, varscan2
- PRKDC | c.747T>A p.F249L | Missense Mutation (SNP) | VAF 24/210 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.014); catalogued as rs1203423113; called by muse, mutect2, varscan2
- RBM10 | c.725-1G>A p.X242_splice | Splice Site (SNP) | VAF 62/150 reads (41%) | catalogued as COSV61313425; called by muse, mutect2, varscan2
- RYR2 | c.7157A>G p.N2386S | Missense Mutation (SNP) | VAF 52/143 reads (36%) | SIFT tolerated (0.1); PolyPhen benign (0.03); catalogued as CM010423; called by muse, mutect2, varscan2
- SPICE1 | c.1569G>T p.K523N | Missense Mutation (SNP) | VAF 21/506 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV55618562; called by muse, mutect2
- SPIRE2 | c.481G>A p.V161I | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.19); PolyPhen benign (0.054); catalogued as rs775449867; called by muse, varscan2
- TRIM54 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 36/208 reads (17%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.586); catalogued as rs748843079, COSV56085510; called by muse, mutect2, varscan2
- TTN | c.53255G>C p.R17752T (on ENST00000591111; = p.R10328T on NM_003319.4) | Missense Mutation (SNP) | VAF 181/420 reads (43%) | PolyPhen probably damaging (0.996); catalogued as COSV60298661, COSV60308843; called by muse, mutect2, varscan2
- VAV2 | c.668A>G p.N223S (on ENST00000371850 / NM_001134398.2; = p.N218S on NM_003371.4) | Missense Mutation (SNP) | VAF 51/95 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.021); catalogued as rs1250209692; called by muse, mutect2, varscan2
- XIRP2 | c.224C>A p.P75Q | Missense Mutation (SNP) | VAF 46/260 reads (18%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.912); catalogued as COSV54691555; called by muse, mutect2, varscan2
- ZIC4 | c.923C>A p.S308* | Nonsense Mutation (SNP) | VAF 78/438 reads (18%) | catalogued as COSV67171209; called by muse, mutect2, varscan2
- ZNF236 | c.329C>G p.A110G | Missense Mutation (SNP) | VAF 23/88 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.952); catalogued as COSV99470953; called by muse, mutect2, varscan2
- ZNF3 | c.1084C>G p.H362D | Missense Mutation (SNP) | VAF 40/279 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52796368; called by muse, mutect2, varscan2
- ZNF362 | c.838G>A p.V280I | Missense Mutation (SNP) | VAF 68/328 reads (21%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as rs745767522; called by muse, mutect2, varscan2
- ZNF556 | c.303G>C p.E101D | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (0.27); PolyPhen benign (0.021); catalogued as rs1489848799, COSV56912081, COSV56912579; called by muse, mutect2, varscan2
- ABCA7 | c.4157del p.N1386Tfs*18 | Frame Shift Del (DEL) | VAF 28/152 reads (18%) | called by mutect2, pindel
- ACER3 | c.704+2T>C p.X235_splice | Splice Site (SNP) | VAF 39/92 reads (42%) | called by muse, mutect2, varscan2
- ADGRF4 | c.141G>T p.R47S | Missense Mutation (SNP) | VAF 23/202 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- AKAP1 | c.1162A>T p.S388C | Missense Mutation (SNP) | VAF 95/309 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); called by muse, mutect2, varscan2
- AKAP6 | c.2848A>G p.M950V | Missense Mutation (SNP) | VAF 34/277 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); called by muse, mutect2, varscan2
- ATP10B | c.2453T>A p.I818N | Missense Mutation (SNP) | VAF 167/314 reads (53%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); called by muse, mutect2, varscan2
- ATRNL1 | c.2074A>T p.I692F | Missense Mutation (SNP) | VAF 20/229 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.307); called by muse, mutect2
- CAAP1 | c.306A>G p.E102= | Splice Region (SNP) | VAF 22/69 reads (32%) | called by muse, mutect2
- CCDC179 | c.115A>T p.M39L | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT tolerated (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- CD5L | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 62/605 reads (10%) | SIFT tolerated (0.72); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- CDRT15L2 | c.264T>C p.H88= | Splice Region (SNP) | VAF 24/128 reads (19%) | called by muse, mutect2
- COL21A1 | c.2091+4T>C | Splice Region (SNP) | VAF 71/218 reads (33%) | called by muse, mutect2, varscan2
- CSF2RB | c.1520G>A p.S507N | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.23); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- CSMD3 | c.10531A>G p.K3511E (on ENST00000297405 / NM_001363185.1; = p.K3342E on NM_052900.3) | Missense Mutation (SNP) | VAF 158/373 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- DHX37 | c.273C>G p.S91R | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.079); called by muse, varscan2
- DLG2 | c.1741G>T p.A581S | Missense Mutation (SNP) | VAF 17/159 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- DNAH8 | c.11280T>G p.F3760L | Missense Mutation (SNP) | VAF 24/119 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); called by muse, mutect2, varscan2
- FAM13A | c.2124G>C p.W708C | Missense Mutation (SNP) | VAF 23/268 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- FAM161B | c.1957G>A p.V653I (on ENST00000651776; = p.V590I on NM_152445.3) | Missense Mutation (SNP) | VAF 47/135 reads (35%) | SIFT tolerated (0.07); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- FAT4 | c.14332C>T p.Q4778* | Nonsense Mutation (SNP) | VAF 35/213 reads (16%) | called by muse, mutect2, varscan2
- GDPD5 | c.1596G>T p.Q532H | Missense Mutation (SNP) | VAF 42/393 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- GSTA4 | c.662G>T p.R221M | Missense Mutation (SNP) | VAF 25/241 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- HCN4 | c.433C>T p.P145S | Missense Mutation (SNP) | VAF 20/80 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.284); called by muse, mutect2, varscan2
- HELB | c.826G>C p.A276P | Missense Mutation (SNP) | VAF 22/81 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.77); called by muse, varscan2
- HRH4 | c.440A>G p.N147S | Missense Mutation (SNP) | VAF 27/255 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- HTR1F | c.37T>A p.S13T | Missense Mutation (SNP) | VAF 40/102 reads (39%) | SIFT tolerated (0.64); PolyPhen benign (0); called by muse, mutect2, varscan2
- IGKV1D-42 | c.194C>G p.S65C | Missense Mutation (SNP) | VAF 28/314 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); called by muse, mutect2
- INTS1 | c.5578G>T p.A1860S | Missense Mutation (SNP) | VAF 48/304 reads (16%) | SIFT tolerated (0.55); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- IZUMO1 | c.619G>T p.E207* | Nonsense Mutation (SNP) | VAF 25/59 reads (42%) | called by muse, mutect2, varscan2
- KAT8 | c.473A>T p.E158V | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.325); called by muse, mutect2, varscan2
- KIDINS220 | c.2110T>C p.F704L | Missense Mutation (SNP) | VAF 175/423 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LRRIQ3 | c.1436T>A p.I479N | Missense Mutation (SNP) | VAF 16/80 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); called by muse, mutect2, varscan2
- LYST | c.308A>T p.D103V | Missense Mutation (SNP) | VAF 70/184 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.432); called by muse, mutect2, varscan2
- MAP2 | c.1303C>T p.L435F | Missense Mutation (SNP) | VAF 37/186 reads (20%) | SIFT deleterious, low confidence (0.04); PolyPhen possibly damaging (0.577); called by muse, mutect2, varscan2
- MDGA2 | c.1684del p.M562Wfs*8 (on ENST00000399232 / NM_001113498.2; = p.M264Wfs*8 on NM_182830.4) | Frame Shift Del (DEL) | VAF 37/332 reads (11%) | called by pindel, varscan2
- MPP5 | c.690G>T p.Q230H | Missense Mutation (SNP) | VAF 64/150 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MRTFB | c.2017G>A p.V673I | Missense Mutation (SNP) | VAF 104/269 reads (39%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MUC12 | c.14462G>T p.G4821V (on ENST00000379442; = p.G4678V on NM_001164462.1) | Missense Mutation (SNP) | VAF 102/575 reads (18%) | SIFT deleterious, low confidence (0.04); called by muse, mutect2, varscan2
- NALCN | c.175A>T p.M59L | Missense Mutation (SNP) | VAF 39/183 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0); called by muse, mutect2, varscan2
- NCOA2 | c.1594A>T p.S532C | Missense Mutation (SNP) | VAF 66/264 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- NPY1R | c.68C>G p.A23G | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.43); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- NRN1L | c.44_48dup p.A17Pfs*4 | Frame Shift Ins (INS) | VAF 132/516 reads (26%) | called by mutect2, pindel, varscan2
- OR4X2 | c.137G>T p.S46I | Missense Mutation (SNP) | VAF 48/260 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- OR8G5 | c.852G>T p.M284I | Missense Mutation (SNP) | VAF 38/316 reads (12%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.615); called by muse, varscan2
- PBX1 | c.7G>C p.E3Q | Missense Mutation (SNP) | VAF 47/348 reads (14%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.586); called by muse, mutect2, varscan2
- PHOX2A | c.23C>A p.S8* | Nonsense Mutation (SNP) | VAF 8/15 reads (53%) | called by muse, mutect2, varscan2
- PLEKHA5 | c.2310A>T p.E770D | Missense Mutation (SNP) | VAF 22/198 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PRKCQ | c.1679T>A p.V560E | Missense Mutation (SNP) | VAF 24/114 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- PZP | c.1464G>T p.E488D | Missense Mutation (SNP) | VAF 14/146 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.072); called by muse, mutect2
- RNF216 | c.116A>T p.D39V | Missense Mutation (SNP) | VAF 67/200 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- RYR2 | c.10798G>A p.V3600I | Missense Mutation (SNP) | VAF 39/89 reads (44%) | SIFT tolerated (0.22); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- SBF2 | c.4261A>C p.T1421P | Missense Mutation (SNP) | VAF 56/269 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.319); called by muse, mutect2, varscan2
- SLC7A1 | c.1089dup p.A364Cfs*4 | Frame Shift Ins (INS) | VAF 54/275 reads (20%) | called by mutect2, pindel, varscan2
- SLC9C2 | c.2137A>G p.I713V | Missense Mutation (SNP) | VAF 28/65 reads (43%) | SIFT tolerated (0.23); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- SOCS7 | c.1114C>T p.P372S | Missense Mutation (SNP) | VAF 76/253 reads (30%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.623); called by muse, mutect2, varscan2
- SPTA1 | c.1825G>T p.D609Y | Missense Mutation (SNP) | VAF 61/472 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.863); called by muse, mutect2, varscan2
- TDRD6 | c.4604G>A p.W1535* | Nonsense Mutation (SNP) | VAF 24/143 reads (17%) | called by muse, mutect2, varscan2
- TMEM151A | c.1010G>A p.R337H | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TOM1L2 | c.686A>T p.D229V (on ENST00000379504 / NM_001350333.2; = p.D179V on NM_001033551.3) | Missense Mutation (SNP) | VAF 33/200 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSPYL5 | c.1136A>T p.Q379L | Missense Mutation (SNP) | VAF 38/482 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TSR1 | c.2273A>T p.K758M | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.516); called by muse, mutect2, varscan2
- TTN | c.84395T>C p.I28132T (on ENST00000591111; = p.I20708T on NM_003319.4) | Missense Mutation (SNP) | VAF 48/133 reads (36%) | PolyPhen benign (0); called by muse, mutect2, varscan2
- VCL | c.575T>G p.V192G | Missense Mutation (SNP) | VAF 64/573 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- WWC2 | c.3364C>A p.L1122M | Missense Mutation (SNP) | VAF 28/188 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ZNF143 | c.1675G>A p.E559K | Missense Mutation (SNP) | VAF 22/120 reads (18%) | SIFT deleterious (0.05); PolyPhen benign (0.162); called by muse, mutect2
- ZNF208 | c.1469C>A p.T490N | Missense Mutation (SNP) | VAF 64/306 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.135); called by muse, mutect2, varscan2
- ZNF536 | c.2848C>T p.H950Y | Missense Mutation (SNP) | VAF 32/250 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZNF536 | c.3619del p.D1207Tfs*56 | Frame Shift Del (DEL) | VAF 46/437 reads (11%) | called by mutect2, pindel, varscan2
- CDR1 | c.183G>A p.T61= | Silent (SNP) | VAF 73/145 reads (50%) | catalogued as rs773964280, COSV100983416; called by muse, mutect2, varscan2
- CKB | c.627C>T p.R209= | Silent (SNP) | VAF 77/251 reads (31%) | called by muse, mutect2, varscan2
- CNNM1 | c.2166T>G p.S722= | Silent (SNP) | VAF 45/111 reads (41%) | called by muse, mutect2, varscan2
- DCDC2 | c.642G>A p.K214= | Silent (SNP) | VAF 32/300 reads (11%) | called by muse, mutect2, varscan2
- DCHS1 | c.4377C>T p.R1459= | Silent (SNP) | VAF 61/283 reads (22%) | catalogued as rs1419260216; called by muse, mutect2, varscan2
- DYRK2 | c.852C>T p.V284= (on ENST00000344096 / NM_006482.3; = p.V211= on NM_003583.4) | Silent (SNP) | VAF 438/3535 reads (12%) | called by muse, mutect2, varscan2
- EPPK1 | c.1200C>T p.A400= | Silent (SNP) | VAF 234/509 reads (46%) | called by muse, mutect2, varscan2
- FEM1A | c.786G>A p.Q262= | Silent (SNP) | VAF 69/333 reads (21%) | catalogued as rs772150769; called by muse, mutect2, varscan2
- HFM1 | c.3561A>T p.S1187= | Silent (SNP) | VAF 8/24 reads (33%) | called by muse, mutect2, varscan2
- MPP5 | c.1143G>T p.V381= | Silent (SNP) | VAF 21/167 reads (13%) | called by muse, mutect2, varscan2
- NT5C2 | c.1167C>T p.F389= | Silent (SNP) | VAF 27/93 reads (29%) | catalogued as rs762471005, COSV58414893; called by muse, mutect2, varscan2
- OAS2 | c.840G>A p.L280= | Silent (SNP) | VAF 4/39 reads (10%) | called by muse, varscan2
- OTOR | c.288C>T p.V96= | Silent (SNP) | VAF 78/243 reads (32%) | catalogued as rs373566609; called by muse, mutect2, varscan2
- PSMD6 | c.525C>T p.D175= | Silent (SNP) | VAF 11/114 reads (10%) | called by muse, mutect2
- RPP25L | c.210C>T p.C70= | Silent (SNP) | VAF 45/325 reads (14%) | catalogued as rs750867710, COSV99427107; called by muse, mutect2, varscan2
- RPS3A | c.414C>T p.F138= | Silent (SNP) | VAF 35/271 reads (13%) | called by muse, mutect2, varscan2
- SGSM1 | c.579C>T p.T193= | Silent (SNP) | VAF 48/289 reads (17%) | catalogued as rs764171405, COSV101240457; called by muse, mutect2, varscan2
- SLC41A3 | c.471G>A p.V157= | Silent (SNP) | VAF 141/323 reads (44%) | called by muse, mutect2, varscan2
- SPAG17 | c.2922C>T p.N974= | Silent (SNP) | VAF 95/247 reads (38%) | catalogued as rs111930764, COSV100310362; called by muse, mutect2, varscan2
- SPANXB1 | c.184A>C p.R62= | Silent (SNP) | VAF 58/1788 reads (3%) | called by muse, mutect2
- TYSND1 | c.1134A>G p.A378= | Silent (SNP) | VAF 19/49 reads (39%) | called by muse, mutect2, varscan2
- WHAMM | c.648A>T p.A216= | Silent (SNP) | VAF 20/127 reads (16%) | called by muse, mutect2, varscan2
- ZBTB47 | c.471C>T p.R157= | Silent (SNP) | VAF 7/81 reads (9%) | catalogued as rs927193223, COSV51763649; called by muse, mutect2
- ZNF479 | c.1560C>A p.P520= | Silent (SNP) | VAF 31/200 reads (16%) | called by muse, varscan2
- AIFM3 | c.-27C>T | 5'UTR (SNP) | VAF 128/362 reads (35%) | called by muse, mutect2, varscan2
- AL121758.1 | c.*489A>G | 3'UTR (SNP) | VAF 33/175 reads (19%) | called by muse, mutect2, varscan2
- ANO4 | c.-65C>T | 5'UTR (SNP) | VAF 37/261 reads (14%) | catalogued as rs373057963, COSV54600188; called by muse, mutect2, varscan2
- CDKN2B | c.*26C>T | 3'UTR (SNP) | VAF 210/534 reads (39%) | catalogued as rs930061540; called by muse, mutect2, varscan2
- CETN3 | c.461-2404C>A | Intron (SNP) | VAF 61/125 reads (49%) | catalogued as rs1031228032; called by muse, mutect2, varscan2
- CKB | c.481+14G>A | Intron (SNP) | VAF 101/195 reads (52%) | called by muse, mutect2, varscan2
- EIF2AK1 | c.118+795T>G | Intron (SNP) | VAF 124/317 reads (39%) | called by muse, mutect2, varscan2
- HMGN1P30 | n.77C>T | RNA (SNP) | VAF 48/272 reads (18%) | catalogued as rs376794568; called by muse, mutect2, varscan2
- MIR1246 | n.70C>A | RNA (SNP) | VAF 6/48 reads (13%) | called by muse, mutect2, varscan2
- MIR29B2CHG | n.244G>A | RNA (SNP) | VAF 31/137 reads (23%) | catalogued as rs1348196458; called by muse, mutect2, varscan2
- MRPS5 | chr2:95121811 C>T | 5'Flank (SNP) | VAF 100/326 reads (31%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67920G>T | Intron (SNP) | VAF 33/191 reads (17%) | called by muse, mutect2, varscan2
- PCDHGA3 | c.2425-67919C>T | Intron (SNP) | VAF 33/188 reads (18%) | called by muse, mutect2, varscan2
- PHEX | c.-10G>A | 5'UTR (SNP) | VAF 65/137 reads (47%) | catalogued as rs1057515841, COSV65076585; called by muse, mutect2, varscan2
- PRR34 | n.477del | RNA (DEL) | VAF 33/244 reads (14%) | called by mutect2, pindel, varscan2
- SLC6A15 | c.756+74C>G | Intron (SNP) | VAF 50/138 reads (36%) | called by muse, mutect2
- SYNE1 | c.16711-48T>A | Intron (SNP) | VAF 53/165 reads (32%) | called by muse, mutect2, varscan2
